MMRF case MMRF_1790 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1c0cb072-09ff-45d9-a28a-1e8169c82d5f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Dead; Days to death: 983 days (2.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.8 years (28,045 days); ISS stage: III; Days to last known disease status: 983 days (2.7 years); Days to last follow up: 983 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Bendamustine; Regimen or line of therapy: Second line of therapy; Days to treatment start: 359 days; Days to treatment end: 547 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 359 days; Days to treatment end: 554 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 614 days (1.7 years); Days to treatment end: 663 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 614 days (1.7 years); Days to treatment end: 660 days (1.8 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 677 days (1.9 years); Days to treatment end: 739 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 677 days (1.9 years); Days to treatment end: 740 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 780 days (2.1 years); Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 780 days (2.1 years); Days to treatment end: 813 days (2.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 828 days (2.3 years); Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 926 days (2.5 years); Days to treatment end: 962 days (2.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 983.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 46.8 g/L; Immunoglobulin A 0.227 g/L; Immunoglobulin M 0.127 g/L; Beta 2 Microglobulin 6.3 µg/mL; Lactate Dehydrogenase 5.6 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.63 ×10⁹/L; Absolute Neutrophil 1.05 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 81.3 µmol/L; Albumin 35 g/L; Total Protein 9.4 g/dL; C-Reactive Protein 0.41 mg/dL.
- Day 95: Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.168 g/L; Immunoglobulin M 0.116 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.87 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.5 mmol/L.
- Day 186 (ECOG 1): M Protein 1.23 g/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.208 g/L; Immunoglobulin M 0.201 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.59 ×10⁹/L; Absolute Neutrophil 4.44 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Albumin 37.4 g/L; Total Protein 6.6 g/dL.
- Day 268 (ECOG 1): M Protein 1.91 g/dL; Immunoglobulin G 22.3 g/L; Immunoglobulin A 0.198 g/L; Immunoglobulin M 0.222 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.33 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.07 mmol/L.
- Day 359 (ECOG 1): M Protein 3.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.598 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 48.5 g/L; Immunoglobulin A 0.204 g/L; Immunoglobulin M 0.206 g/L; Beta 2 Microglobulin 7.32 µg/mL; Lactate Dehydrogenase 5.27 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.84 ×10⁹/L; Absolute Neutrophil 1.37 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 10.1 g/dL.
- Day 442: M Protein 1.09 g/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.088 g/L; Immunoglobulin M 0.097 g/L; Lactate Dehydrogenase 6.3 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.29 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L.
- Day 550 (ECOG 1): M Protein 1.46 g/dL; Immunoglobulin G 18.7 g/L; Immunoglobulin A 0.074 g/L; Immunoglobulin M 0.115 g/L; Lactate Dehydrogenase 7.67 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.02 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Total Protein 6.9 g/dL.
- Day 624 (ECOG 2): M Protein 3.31 g/dL; Immunoglobulin G 44.6 g/L; Immunoglobulin A 0.028 g/L; Immunoglobulin M 0.101 g/L; Hemoglobin 8 mmol/L; Leukocytes 7.28 ×10⁹/L; Absolute Neutrophil 4.62 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 110 µmol/L; Calcium 2.53 mmol/L.
- Day 722 (ECOG 2): M Protein 3.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.062 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 45.6 g/L; Immunoglobulin A 0.014 g/L; Immunoglobulin M 0.038 g/L; Lactate Dehydrogenase 9 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.27 ×10⁹/L; Absolute Neutrophil 5.45 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 7.5 g/dL.
- Day 814: M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.39 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.0667 g/L; Immunoglobulin M 0.0789 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.87 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 4.79 mmol/L.
- Day 930 (ECOG 3): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.073 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 46 g/L; Immunoglobulin A 0.01 g/L; Immunoglobulin M 0.043 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.77 ×10⁹/L; Absolute Neutrophil 0.665 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 72.5 µmol/L; Calcium 1.8 mmol/L.

Other clinical attributes
- Day 1: Weight: 66 kg; Height: 146 cm.

Family history
- Relative with cancer history: no.

Biospecimens (6 samples)
- Sample MMRF_1790_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1790_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1790_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 359 days.
- Sample MMRF_1790_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 624 days (1.7 years).
- Sample MMRF_1790_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 930 days (2.5 years).
- Sample MMRF_1790_4_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Days to sample procurement: 930 days (2.5 years).
